FM case AD8317 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/37401660-2300-4fee-9ea8-e676963b0590

Male, 64.1 years: Acinar cell carcinoma (ICD-O-3 8550/3) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
